Gene-level copy-number profile of tumor specimen TCGA-NC-A5HD-01A from TCGA case TCGA-NC-A5HD, project TCGA-LUSC (Lung Squamous Cell Carcinoma). Sex at birth: male; Vital status: Dead; Primary diagnosis: Squamous cell carcinoma, NOS; Tissue or organ of origin: Upper lobe, lung; AJCC pathologic stage: Stage IIB; Age at diagnosis: 79.2 years (28,916 days).
Specimen TCGA-NC-A5HD-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-LUSC.55be848b-993a-47ba-929d-1c7b29619f54.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-NC-A5HD-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 809 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2; ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/1ecdece6-ab22-404e-a827-ae93a9f3b32a

Most common (modal) total copy number across autosomal genes: 1 — below the diploid value of 2.
Genes by total copy number (all chromosomes): copy number 0: 14; copy number 1: 30,728; copy number 2: 23,973; copy number 3: 3,630; copy number 4: 762; copy number 5: 66; copy number 6: 480; copy number 7: 26; copy number 9: 95; copy number 13: 40.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-NC-A5HD-01A-11D-A26L-01): tumor purity 0.61, ploidy 2.92, whole-genome doublings 1.

Homozygous deletions (total copy number 0; autosomes only): 14 genes in 5 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr3:188,562,238–188,568,666, 1 gene: LPP-AS1.
- chr8:4,633,065–4,635,654, 1 gene: AC022068.1.
- chr9:21,802,636–22,029,594, 1 gene (within-gene range 0–1): AL359922.1.
- chr9:21,929,457–22,214,672, 10 genes: ERVFRD-3, CDKN2A-DT, CDKN2A, CDKN2B-AS1, AL449423.1, CDKN2B, UBA52P6, AL354709.1, AL354709.2, AL157937.1.
- chr10:61,901,684–62,096,944, 1 gene (within-gene range 0–1): ARID5B.

Amplified relative to the modal value (total copy number ≥ 3, i.e. more than twice the modal value of 1; autosomes only): 5,099 genes in 22 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr1:209,325,392–209,432,838, 4 genes, copy number 4: LINC01696, LINC01698, MIR205HG, MIR205.
- chr1:237,862,175–240,698,429, 44 genes, copy number 3: AL359924.1, ZP4, AL590396.1, MTCO1P38, AL590396.2, AL590396.3, MTRNR2L11, MTCYBP15, MTND6P15, MTND5P18, YWHAQP9, AL356010.2, AL356010.1, RNU6-725P, LINC01139, AL359551.1, KRT18P32, MIPEPP2, AL583825.1, AL590135.1, AC093426.2, AC093426.1, CHRM3, CHRM3-AS2, CHRM3-AS1, AL356361.2, AL356361.1, AL356361.3, RPS7P5, FMN2, AL359918.1, Y_RNA, ADH5P3, AL359918.2, Y_RNA, AL590490.1, GREM2, AL358176.1, AL358176.2, AL358176.4, AL358176.3, RNU5F-8P, AL358176.5, Y_RNA.
- chr2:179,101,678–179,861,612, 4 genes, copy number 3 (within-gene range 2–3): SESTD1, AC093911.1, RAD52P1, ZNF385B.
- chr2:234,682,668–236,131,800, 11 genes, copy number 3 (within-gene range 2–3): LINC01173, AC104394.1, AC010148.1, SH3BP4, AC114814.1, CEP19P1, AC114814.2, AGAP1, AGAP1-IT1, AC064874.1, TMSB10P1.
- chr3:93,843,764–186,570,543, 1,527 genes, copy number 3–13 (broad region; genes not listed).
- chr3:192,029,880–193,844,024, 26 genes, copy number 7: AC026320.1, AC026320.3, RN7SKP222, FGF12, FGF12-AS1, FGF12-AS2, FGF12-AS3, AC026671.1, RNU1-20P, MB21D2, AC092966.1, VEZF1P1, PLAAT1, ATP13A5, ATP13A5-AS1, ATP13A4, ATP13A4-AS1, AC048351.1, OPA1, OPA1-AS1, Y_RNA, RN7SL447P, AC069421.1, AC069421.2, AC069421.3, LINC02038.
- chr5:58,198–45,895,970, 710 genes, copy number 3 (broad region; genes not listed).
- chr6:26,634,383–26,956,554, 5 genes, copy number 4 (within-gene range 1–4): ZNF322, AL513548.4, AL513548.1, GUSBP2, POM121L6P.
- chr8:29,815,004–35,796,550, 91 genes, copy number 3 (broad region; genes not listed).
- chr8:89,243,401–138,083,657, 680 genes, copy number 3 (within-gene range 2–3) (broad region; genes not listed).
- chr8:140,940,562–145,066,685, 193 genes, copy number 3 (broad region; genes not listed).
- chr11:49,558,546–49,982,535, 18 genes, copy number 3 (within-gene range 1–3): AC136759.1, AC130364.1, AC130364.2, TRIM51FP, AP006587.5, AP006587.6, AP006587.4, AP006587.3, TRIM51DP, AP006587.1, AP006587.2, OR4A1P, OR4A49P, OR4A18P, OR4A19P, OR4R3P, OR4C13, OR4C12.
- chr11:81,552,226–85,627,922, 38 genes, copy number 4–5 (within-gene range 2–5): MTND4LP18, MTND6P25, MIR4300HG, AP002802.2, MIR4300, AP002802.1, AP000793.1, RPS28P7, FAM181B, LINC02734, RBMXP3, PRCP, EIF2S2P6, DDIAS, AP000893.1, AP000893.2, RAB30, AP001767.1, SNORA70E, RAB30-DT, AP001767.2, AP001767.3, COX5BP4, C1DP5, BCAS2P1, PCF11, AP000873.4, AP000873.2, PCF11-AS1, ANKRD42, CKS1BP4, AP000873.3, AP000873.1, CCDC90B, AP000446.1, CYCSP28, AP000446.2, DLG2.
- chr11:84,545,131–113,278,436, 510 genes, copy number 3–4 (within-gene range 2–4) (broad region; genes not listed).
- chr11:122,655,722–124,461,485, 73 genes, copy number 4–5 (broad region; genes not listed).
- chr12:64,759,496–64,977,509, 1 gene, copy number 3 (within-gene range 2–3): AC078815.1.
- chr12:64,867,956–66,066,338, 27 genes, copy number 3: RPL7P39, LINC02389, LINC02231, RNU6ATAC42P, AC135895.1, WIF1, RNU6-166P, APOOP3, LEMD3, AC026124.2, MSRB3, AC026124.1, KRT18P60, AC025419.1, AC090023.1, LINC02454, AC090023.2, PCNPP3, RPSAP52, HMGA2, AC107308.1, HMGA2-AS1, AC090673.1, MIR6074, LINC02425, RPL21P18, RNA5SP362.
- chr12:67,131,567–68,576,136, 30 genes, copy number 3: RAB11AP2, GGTA2P, CAND1, AC078983.1, MRPL40P1, NTAN1P3, LINC02420, LINC02408, LINC02442, DYRK2, AC078777.1, LINC02421, AC022513.1, LINC01479, AC005294.1, IFNG-AS1, RPL39P28, HNRNPA1P70, AC007458.1, IFNG, IL26, IL22, MDM1, LINC02384, AC022511.1, AC008033.3, AC008033.1, AC008033.2, RPSAP12, Metazoa_SRP.
- chr14:84,951,274–87,655,294, 20 genes, copy number 3: AL163642.1, AL163642.2, AL357172.1, AL049775.2, LINC02329, LINC00911, AL049775.1, AL049775.3, FLRT2, LINC02328, LINC02316, AL161753.1, LINC02309, LINC01148, AL358292.1, AL352955.1, AL157688.1, LINC02296, AL135746.1, LINC02330.
- chr16:27,787,528–28,240,668, 8 genes, copy number 4 (within-gene range 1–4): GSG1L, RNU6-159P, RNU6-1241P, XPO6, TPRKBP2, AC136611.1, RNY1P10, GAPDHP35.
- chr20:87,250–32,850,405, 641 genes, copy number 3 (within-gene range 2–3) (broad region; genes not listed).
- chr22:17,734,138–24,442,356, 438 genes, copy number 3–6 (within-gene range 1–6) (broad region; genes not listed).

Autosomal genes at a single copy (total copy number 1): 28,307. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
